Somatic mutation profile of tumor specimen 1105268 (aliquot 7316UP-2726-1105268) from CPTAC case C760878, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Frontal lobe; Tumor grade: G3.
Specimen 1105268: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab4cf38b-cb2a-4615-bf67-b45e12a0af1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105278 (Blood Derived Normal), aliquot 7316UP-1843-1105278; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9c85171-8691-4cde-912d-9746844a3782

The open-access MAF lists 106 somatic variants for this specimen: 75 protein-altering or splice-affecting, 22 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 22, Frame Shift Del 11, Intron 7, Nonsense Mutation 5, Splice Site 4, 5'UTR 1, In Frame Del 1, Frame Shift Ins 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 7081/7414 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 32/112 reads (29%) | catalogued as rs750862917; called by mutect2, pindel, varscan2
- AFF1 | c.1236_1239del p.H412Qfs*86 | Frame Shift Del (DEL) | VAF 40/178 reads (22%) | catalogued as rs765113099; called by pindel, varscan2
- BIRC6 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); catalogued as rs373105075; called by muse, mutect2, varscan2
- C3 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 279/978 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765821415, COSV55568720; called by muse, mutect2, varscan2
- CFAP20DC | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 59/135 reads (44%) | catalogued as rs952156491; called by mutect2, varscan2
- CIITA | c.3311C>T p.T1104M | Missense Mutation (SNP) | VAF 208/483 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs367805896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP4A22 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 86/209 reads (41%) | catalogued as rs1182232056, COSV53738126; called by muse, mutect2, varscan2
- EDDM3A | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 80/187 reads (43%) | catalogued as rs768794732, COSV58795108, COSV58795417; called by muse, mutect2, varscan2
- EPS15L1 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 93/330 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as rs750367780; called by muse, mutect2, varscan2
- FAM53A | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as rs559109336, COSV57401825; called by muse, mutect2, varscan2
- FAT4 | c.5053C>T p.R1685* | Nonsense Mutation (SNP) | VAF 62/179 reads (35%) | catalogued as rs760759561, COSV67882267; called by muse, mutect2, varscan2
- FRAS1 | c.4814C>T p.A1605V | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs749776166; called by muse, mutect2, varscan2
- GASK1B | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV56709057, COSV99030607; called by muse, mutect2, varscan2
- GBP3 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 101/255 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs145016759; called by muse, mutect2, varscan2
- HIRA | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs376487965; called by muse, mutect2, varscan2
- HYDIN | c.10129C>T p.R3377C | Missense Mutation (SNP) | VAF 92/297 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs779031423, COSV101151299, COSV101157939; called by muse, mutect2, varscan2
- N4BP2 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs780476202, COSV54699826; called by muse, mutect2, varscan2
- NLRP4 | c.554C>G p.T185R | Missense Mutation (SNP) | VAF 96/375 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV56713550; called by muse, mutect2, varscan2
- OR4A15 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 117/297 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs374555766, COSV59036488; called by muse, mutect2, varscan2
- PCDH11Y | c.208G>A p.V70I (on ENST00000400457 / NM_032973.2; = p.V59I on NM_032971.3) | Missense Mutation (SNP) | VAF 332/365 reads (91%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV53082348; called by muse, mutect2, varscan2
- PROKR1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 86/175 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs149410240; called by muse, mutect2, varscan2
- RAD21L1 | c.349T>A p.F117I | Missense Mutation (SNP) | VAF 88/234 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV104369649; called by muse, mutect2, varscan2
- SLC25A21 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 65/139 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs758995590; called by muse, mutect2, varscan2
- SLC6A17 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 85/184 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58991663; called by muse, mutect2, varscan2
- SNX13 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 124/512 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1212626732; called by muse, mutect2, varscan2
- SPOCK3 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 125/367 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446612, COSV100692812; called by muse, mutect2, varscan2
- SYT6 | c.746G>A p.R249H (on ENST00000610222 / NM_001366225.1; = p.R164H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 194/511 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs139165674, COSV101059648; called by muse, mutect2, varscan2
- TLR2 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 67/184 reads (36%) | catalogued as rs989773958, COSV52607172; called by muse, mutect2, varscan2
- TMEM94 | c.3433C>T p.H1145Y | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV58595309; called by muse, mutect2, varscan2
- TRPC6 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437212772; called by muse, mutect2, varscan2
- UNC13B | c.278del p.P93Lfs*7 | Frame Shift Del (DEL) | VAF 99/299 reads (33%) | catalogued as COSV101037460; called by mutect2, pindel, varscan2
- ZNF407 | c.5666C>T p.T1889M | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs553117551, COSV55254908; called by muse, mutect2, varscan2
- AKAP13 | c.4582G>C p.A1528P | Missense Mutation (SNP) | VAF 119/247 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- AKR7A3 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 89/203 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ALPP | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 114/257 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO3 | c.2764-1G>A p.X922_splice | Splice Site (SNP) | VAF 107/224 reads (48%) | called by muse, mutect2, varscan2
- ARMC10 | c.434del p.N145Tfs*15 | Frame Shift Del (DEL) | VAF 3591/7339 reads (49%) | called by mutect2, pindel, varscan2
- ATP1B1 | c.101A>T p.K34M | Missense Mutation (SNP) | VAF 84/166 reads (51%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRIP1 | c.3398C>A p.T1133K | Missense Mutation (SNP) | VAF 110/287 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CPNE1 | c.546_555del p.N183Tfs*83 (on ENST00000352393; = p.N188Tfs*83 on NM_003915.5) | Frame Shift Del (DEL) | VAF 74/227 reads (33%) | called by mutect2, pindel, varscan2
- CSNK1D | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 217/540 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- EML6 | c.3237T>G p.H1079Q | Missense Mutation (SNP) | VAF 97/235 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GARS1 | c.140_141del p.P47Rfs*14 | Frame Shift Del (DEL) | VAF 233/898 reads (26%) | called by mutect2, pindel, varscan2
- HAUS2 | c.94-2A>G p.X32_splice | Splice Site (SNP) | VAF 43/113 reads (38%) | called by muse, mutect2
- IGBP1P2 | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- IGKV1D-42 | c.185C>G p.P62R | Missense Mutation (SNP) | VAF 106/247 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ITPKA | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 156/386 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- JPH4 | c.695G>C p.G232A | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LAMA1 | c.2572T>G p.S858A | Missense Mutation (SNP) | VAF 169/401 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- LARP4 | c.1130_1139del p.P377Rfs*21 | Frame Shift Del (DEL) | VAF 99/464 reads (21%) | called by mutect2, pindel, varscan2
- LRRC8B | c.1531A>T p.N511Y | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MLLT10 | c.603+1G>A p.X201_splice | Splice Site (SNP) | VAF 53/59 reads (90%) | called by muse, mutect2, varscan2
- MTA3 | c.1657A>G p.S553G (on ENST00000405094 / NM_001330442.2; = p.S496G on NM_001282755.1) | Missense Mutation (SNP) | VAF 145/321 reads (45%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- OR4F17 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 242/1688 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDXDC1 | c.1543_1544del p.P515* | Frame Shift Del (DEL) | VAF 51/150 reads (34%) | called by mutect2, pindel, varscan2
- PRKCH | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 83/189 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- QKI | c.521_523del p.E174del | In Frame Del (DEL) | VAF 34/90 reads (38%) | called by pindel, varscan2
- QRICH2 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 221/575 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- SEC24D | c.442T>G p.S148A | Missense Mutation (SNP) | VAF 130/276 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB2 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGMAR1 | c.645del p.T216Pfs*46 | Frame Shift Del (DEL) | VAF 188/611 reads (31%) | called by mutect2, pindel, varscan2
- SLC6A1 | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 62/150 reads (41%) | called by muse, mutect2, varscan2
- SULF2 | c.1621del p.A541Pfs*11 | Frame Shift Del (DEL) | VAF 166/478 reads (35%) | called by mutect2, pindel, varscan2
- TAT | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 294/651 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEP1 | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, varscan2
- TMEM165 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPST1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 170/637 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- VPS18 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WASL | c.11T>A p.V4D | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YWHAZ | c.389_390insAACGTTACTTGGC p.E131Tfs*5 | Frame Shift Ins (INS) | VAF 46/176 reads (26%) | called by mutect2, varscan2
- ZMIZ1 | c.2822C>G p.P941R | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ZNF229 | c.1598T>C p.L533P | Missense Mutation (SNP) | VAF 123/435 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF236 | c.4098_4099del p.N1367Lfs*17 | Frame Shift Del (DEL) | VAF 67/236 reads (28%) | called by mutect2, pindel, varscan2
- ZNF670 | c.943G>T p.G315C | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AP3B1 | c.1983C>T p.T661= | Silent (SNP) | VAF 159/397 reads (40%) | called by muse, mutect2, varscan2
- CAVIN1 | c.972C>T p.H324= | Silent (SNP) | VAF 181/417 reads (43%) | catalogued as rs1421562805, COSV100824606; called by muse, mutect2, varscan2
- CBFA2T3 | c.1887C>T p.S629= | Silent (SNP) | VAF 85/183 reads (46%) | catalogued as rs750626340; called by muse, mutect2, varscan2
- CYP4Z1 | c.699C>T p.N233= | Silent (SNP) | VAF 44/193 reads (23%) | catalogued as rs370015142; called by muse, mutect2, varscan2
- DPP10 | c.192G>A p.S64= | Silent (SNP) | VAF 68/157 reads (43%) | catalogued as rs201248540; called by muse, mutect2, varscan2
- FLNB | c.6114G>A p.A2038= | Silent (SNP) | VAF 238/517 reads (46%) | catalogued as rs1559730956; called by muse, mutect2, varscan2
- HMGCS2 | c.879C>T p.D293= | Silent (SNP) | VAF 124/294 reads (42%) | catalogued as rs761787433, COSV65569426; called by muse, mutect2, varscan2
- HTR1E | c.105C>G p.L35= | Silent (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- MAGEA12 | c.681G>T p.V227= | Silent (SNP) | VAF 257/299 reads (86%) | called by muse, mutect2, varscan2
- MYLK3 | c.603G>A p.A201= | Silent (SNP) | VAF 46/92 reads (50%) | catalogued as rs781406736; called by muse, varscan2
- OR52J3 | c.654G>A p.S218= | Silent (SNP) | VAF 134/260 reads (52%) | catalogued as rs148600962, COSV66747742; called by muse, mutect2, varscan2
- OR8A1 | c.411T>C p.S137= | Silent (SNP) | VAF 111/214 reads (52%) | catalogued as rs538622740; called by muse, mutect2, varscan2
- OSMR | c.87T>C p.R29= | Silent (SNP) | VAF 73/181 reads (40%) | called by muse, mutect2, varscan2
- POTEJ | c.2622C>T p.D874= | Silent (SNP) | VAF 354/1054 reads (34%) | called by muse, varscan2
- PPP1R3B | c.795C>G p.S265= | Silent (SNP) | VAF 130/319 reads (41%) | catalogued as rs1268134247; called by muse, mutect2, varscan2
- PRDM9 | c.2671A>C p.R891= | Silent (SNP) | VAF 200/483 reads (41%) | called by muse, mutect2, varscan2
- PRRC2A | c.411C>T p.S137= | Silent (SNP) | VAF 99/247 reads (40%) | catalogued as rs761009382, COSV63224694; called by muse, mutect2, varscan2
- SEC14L5 | c.327C>T p.N109= | Silent (SNP) | VAF 71/164 reads (43%) | catalogued as rs375401992; called by muse, mutect2, varscan2
- SERHL2 | c.12C>T p.N4= | Silent (SNP) | VAF 114/389 reads (29%) | called by muse, mutect2, varscan2
- TMCC2 | c.402C>T p.Y134= | Silent (SNP) | VAF 255/533 reads (48%) | catalogued as rs77588763, COSV58005035; called by muse, mutect2, varscan2
- TMEM270 | c.678C>T p.A226= | Silent (SNP) | VAF 231/807 reads (29%) | catalogued as rs201571768; called by muse, mutect2, varscan2
- TPTE2 | c.213A>T p.V71= | Silent (SNP) | VAF 68/103 reads (66%) | called by muse, mutect2, varscan2
- AC010507.1 | chr19:200820 C>T | 3'Flank (SNP) | VAF 72/482 reads (15%) | called by muse, mutect2
- ENY2 | c.230-678C>T | Intron (SNP) | VAF 123/312 reads (39%) | called by muse, mutect2, varscan2
- FCRL5 | c.-21C>G | 5'UTR (SNP) | VAF 136/317 reads (43%) | called by muse, mutect2, varscan2
- HTN3 | c.73-34A>C | Intron (SNP) | VAF 67/138 reads (49%) | catalogued as COSV66879574; called by muse, mutect2, varscan2
- MYO10 | c.21+19724G>A | Intron (SNP) | VAF 133/307 reads (43%) | catalogued as rs772652920, COSV72454035; called by muse, mutect2, varscan2
- SERINC2 | c.39+693C>G | Intron (SNP) | VAF 56/81 reads (69%) | catalogued as rs1448575368; called by muse, mutect2, varscan2
- SNRNP200 | c.5754+39C>G | Intron (SNP) | VAF 228/473 reads (48%) | catalogued as rs746692485; called by muse, mutect2, varscan2
- TSPEAR | c.633+33G>A | Intron (SNP) | VAF 226/555 reads (41%) | catalogued as rs777838829; called by muse, mutect2, varscan2
- TTN | c.10360+1582G>A | Intron (SNP) | VAF 65/168 reads (39%) | called by muse, mutect2, varscan2
